Surgical pathology report (de-identified scan), TCGA case TCGA-91-A4BD, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-91-A4BD-01A (Primary Tumor).

[page 1 of 3]
Operative Procedure: Left lower lobectomy

Specimen Received:

- A: Left lower lobe (FS)
- B: Left inferior pulmonary ligament
- C: Left lower lobe #2
- D: Sub carinal lymph node
- E: AP window
- F: Level 10 lymph node

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: lung, Lower lobe C34.3

hw 9/24/12

Final Pathologic Diagnosis:

- A. Lung, left lower lobe, excision:
Adenocarcinoma with lepidic pattern
Frozen section diagnosis confirmed.
- B. Soft tissue, left inferior pulmonary ligament, excision:
Three lymph nodes, negative for malignancy (0/3).
- C. Lung, left lower lobe #2, excision:
Minimally invasive, non-mucinous adenocarcinoma, well-differentiated.
Surgical margins are negative.
See synoptic report.

Lung cancer synoptic report

Specimen: Lobe of lung (left lower lobe)
Procedure: Lobectomy
Specimen laterality: Left
Tumor site: Left lower lobe
Specimen integrity: Intact
Tumor size: 2.8 cm (greatest dimension)
Tumor focality: Unifocal
Tumor histologic type: Adenocarcinoma, minimally invasive and non-mucinous,
See Note.
Tumor grade: Well differentiated, G1
Visceral pleura invasion: Not identified
Tumor extension: Not identified
Margins:
Bronchial margin: Uninvolved by invasive carcinoma
Vascular margin: Uninvolved by invasive carcinoma
Parenchymal margin: Uninvolved by invasive carcinoma
Parietal pleural margin: Not applicable
Chest wall margin: N/A
Other attached tissue margins: N/A

If all margins uninvolved by invasive carcinoma:
Distance of invasive carcinoma from closest margin: 20 mm

hw 9/18/12

[page 2 of 3]
Specify margin: Bronchial margin

Treatment effect: N/A

Lymph-vascular invasion: Not identified

Pathologic Staging (pTNM):

TNM Descriptors: No descriptors

Primary tumor (pT): pT1b

Regional lymph nodes (pN): pN1

Total number involved/examined: 1/17 (parts B, C, D, E, F)

Left inferior pulmonary ligament: 0/3 (part B)

Peribronchial, left lower lobe: 1/8 (part C)

Subcarinal: 0/3 (part D)

AP window: 0/2 (part E)

Level 10: 0/1 (part F)

Distant metastasis (pM): pMX

Additional pathologic findings: None

D. Lymph node, subcarinal, excision:

Three lymph nodes, negative for malignancy (0/3)

E. Lymph node, AP window, excision:

Two lymph nodes, negative for malignancy (0/2)

F. Lymph node, level 10, excision:

One lymph node, negative for malignancy (0/1)

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:

The tumor consist of primarily adenocarcinoma in situ with multiple minute foci of invasion none of which is greater than 5 mm. The tumor abuts the visceral pleura but does not show invasion.

Intraoperative Consult Diagnosis:

FSA: Left lower lobe:

Adenocarcinoma.

Gross Description:

Received are six specimen containers, all labeled with the patient name,

Part A is received fresh for frozen section evaluation additionally labeled, "left lower lobe (FSA)" and consists of a 1.6 x 1.5 x 0.3 cm portion of pink-tan nodular soft tissue which is submitted for frozen section evaluation (FSA) with residual frozen section tissue submitted in cassette A.

[page 3 of 3]
Part B is received in formalin and additionally labeled, "left inferior pulmonary ligament" and consists of two nodular portions of tan-yellow fibrofatty tissue not otherwise designated and having greatest dimensions of 1.2 and 1.8 cm, submitted in toto in cassette B.

Part C is received in formalin and additionally labeled, "left lower lobe #2" and consists of the product of a left lower lobectomy having overall dimensions of 19.5 x 11 by up to 4 cm. This specimen features essentially intact visceral pleura with the exception of an umbilicated subpleural mass which has been previously incised, the latter of which has dimensions of 2.8 x 2.2 x 1 cm and which approaches to within 2 cm of the closest bronchial margin of resection. This mass appears to remain in a sub visceral pleural location without extension beyond the pleura. This mass arises within the central aspect of the left lower lobe. Sectioning of the remaining lung parenchyma reveals no grossly identifiable lesions. Significant emphysematous change is not grossly identified and there are multiple peribronchial lymph nodes, none of which appear involved by tumor, however exhibit anthracotic pigment. Sections are submitted as follows:

- C1 bronchial and vascular margins of surgical resection left lower lobe of the lung;
- C2-4 representative sections of mass central to left lower lobe;
- C5,6 random unremarkable left lower lobe of lung;
- C7 three whole peribronchial lymph nodes;
- C8 three whole peribronchial lymph nodes;
- C9 largest peribronchial lymph node bisected.

Part D is received in formalin additionally labeled, "subcarinal lymph node" and consists of a single nodular portion of yellow lobulated fibrofatty tissue 2 x 1.8 x 1 cm. Within these tissues are at least three anthracotic laden lymph nodes that range from 0.3 to 0.7 cm in greatest dimension submitted in cassette D1 and remaining tissue submitted in cassette D2. This portion of the case has been submitted in its entirety.

Part E is received in formalin and additionally labeled, "AP window" and consists of a single nodular portion of tan-yellow to gray-tan tissue which is 1.8 x 1 x 0.5 cm. Within this tissue there are two probable lymph nodes which are sectioned and submitted in in cassette E.

Part F is received in formalin and additionally labeled, "Level 10 lymph node" and consists of a single 1.5 cm in greatest dimension anthracotic laden lymph node which is bisected and submitted entirely in cassette F.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken: : Gender: M

Source: NCI Genomic Data Commons file b1172ed5-885c-4ac6-89f1-6aaabed0c21b (TCGA-91-A4BD.5767AA19-6B73-4FC8-BC3E-930044E249A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).